Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5894, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5894-01A (Primary Tumor).

[page 1 of 3]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Metastatic left RCC.

Specimens Submitted:

1: SP: Kidney, adrenal gland and hilar lymph nodes, left; Radical nephrectomy

2: SP: Lymph nodes, periaortic, Dissection

DIAGNOSIS:

1. SP: Kidney, adrenal gland and hilar lymph nodes, left; Radical nephrectomy:

Tumor Type:

Renal cell carcinoma, high grade, with tubulopapillary features (SEE NOTE)

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 6.5 cm.

Local Invasion (for renal cortical types):

Involves renal hilar fat

Renal Vein Invasion:

Angiolymphatic invasion is identified in small vessels and segmental branch of the renal vein.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

A PAS stain demonstrates mild arterionephrosclerosis.

Adrenal Gland:

Involved by metastatic carcinoma

Lymph Nodes:

Number of metastatic nodes:7

Number of nodes examined:7

which includes nodular tumor deposits suggestive of lymph nodes entirely replaced by tumor.

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

NOTE: Immunohistochemical stains show positive staining for racemase while CK7, CD10 and CAIX are negative. The differential diagnosis includes a tumor of the distal nephron, collecting duct carcinoma, and type 2 papillary carcinoma; however renal cell

[page 2 of 3]
[REDACTED]

carcinoma in the setting of hereditary leiomyomatosis is also a consideration. Reviewed a [REDACTED]

2. SP: Lymph nodes, periaortic; Dissection:

Lymph Node Dissection:

Metastatic renal cell carcinoma similar to part one
Number of lymph nodes examined: 10
Number of lymph nodes with metastatic disease: 4
Size of the largest lymph node involved by tumor: 3cm.
Size of the largest metastatic focus : 3 cm.
Extranodal extension is identified

Note:

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be used for investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT

[REDACTED]

Special Studies:

Result	Special Stain	Comment
	PAS	
	CA-1X	
	RACEMASE	
	CK7	
	CD10	
	IMM RECUT	
	NEG CONT	
	H&E(US)	
	RECUT	
	RECUT	
	RECUT	
	RECUT	

Gross Description:

[REDACTED]

1) The specimen is received fresh labeled "Left kidney with hilar lymph nodes" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 307 g in total. The kidney measures 11 x 5 x 4.5 cm. The attached ureter measures 9 cm in length and 0.3 cm in diameter. The attached renal vein measures 12 cm in length and 0.4 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified measuring 5 x 2.3 x 1.4 cm and has a nodular bright yellow cut surface, as well as a 2.3 cm tan solid lesion, grossly identical to the kidney tumor. The kidney is inked black and bivalved to reveal a 6.5 x 3.9 x 3.2 cm solid homogenous fleshy tan somewhat nodular mass located in the upper to mid portion of the kidney, centered at the cortico medullary junction. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 1 cm and the calyces appear normal. Several grossly positive lymph nodes are identified in the hilum, measuring up to 3.2 cm, with renal vein present in the midst of them (the main renal vein is not involved grossly). The specimen is photographed. Representative sections are submitted for [REDACTED] (both kidney and lymph nodes) and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

[page 3 of 3]
[REDACTED]

T -- tumor
THF -- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney
AT - adrenal with tumor
A -- adrenal gland
LN -- lymph nodes (representative sections only if grossly involved)

[REDACTED]

2) The specimen is received fresh, labeled "periaortic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 3.0 cm in greatest dimension. All identified lymph nodes are submitted. Tissue from 3 largest, grossly positive lymph nodes is submitted to [REDACTED]

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes

Summary of Sections:

Part 1: SP: Kidney, adrenal gland and hilar lymph nodes, left; Radical nephrectomy

Block	Sect. Site	PCs
1	A	1
1	AT	1
1	K	1
3	LN	3
1	RP	1
5	T	5
2	THF	2
2	TK	2
2	TSF	2
1	UVM	3

Part 2: SP: Lymph nodes, periaortic; Dissection

Block	Sect. Site	PCs
1	BLN	1
1	LLN	1
2	LN	2

Source: NCI Genomic Data Commons file 4dba7c48-29c9-462d-8e53-841870c9cce5 (TCGA-BQ-5894.A4480208-148C-4317-81F0-AF2B20C0A85C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).